Somatic mutation profile of tumor specimen 0DC462 from CCDI case PBBLMW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Sarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 6.8 years (2,497 days).
Specimen 0DC462: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 981e7ab0-ba0f-42b4-a136-97ce4e6563d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DC460 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c2041d8-d445-4432-ae03-04fb7862f148

The open-access MAF lists 4 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BROX | c.643del p.E215Kfs*30 | Frame Shift Del (DEL) | VAF 322/864 reads (37%) | called by mutect2, varscan2
- CEACAM7 | c.693C>G p.T231= | Silent (SNP) | VAF 13/345 reads (4%) | called by muse, mutect2
- ZNHIT6 | c.1344C>T p.S448= | Silent (SNP) | VAF 111/1469 reads (8%) | called by muse, mutect2
- SYT3 | c.-95C>T | 5'UTR (SNP) | VAF 62/190 reads (33%) | called by muse, mutect2, varscan2
